Somatic mutation profile of tumor specimen TCGA-FC-7961-01A (aliquot TCGA-FC-7961-01A-11D-A29Q-08) from TCGA case TCGA-FC-7961, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.7 years (22,888 days).
Specimen TCGA-FC-7961-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2783817-4c96-4515-bce2-6aaf982dbf16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FC-7961-10A (Blood Derived Normal), aliquot TCGA-FC-7961-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55a9fd1f-a287-45fc-9101-50d72076c939

The open-access MAF lists 48 somatic variants for this specimen: 37 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 27, Silent 11, Frame Shift Ins 4, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.723dup p.E242* | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | catalogued as rs1060500115; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPOP | c.398T>G p.F133C | Missense Mutation (SNP) | VAF 32/168 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1057519967, COSV61653174, COSV61653874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.105dup p.S36Vfs*15 | Frame Shift Ins (INS) | VAF 41/123 reads (33%) | catalogued as rs763538641; called by mutect2, pindel, varscan2
- ADCY9 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53580895; called by muse, mutect2, varscan2
- ARHGAP31 | c.3480G>C p.Q1160H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51798080; called by muse, mutect2, varscan2
- ATP8B4 | c.3122G>A p.S1041N | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV52711910, COSV52722976; called by muse, mutect2, varscan2
- BARD1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs200059956, COSV53616152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CA6 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as COSV66262862, COSV66263121; called by muse, mutect2, varscan2
- CAV3 | c.310G>C p.V104L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs944503745, COSV57480724; called by muse, mutect2, varscan2
- CDCA2 | c.1247A>T p.K416I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57948289; called by muse, mutect2, varscan2
- CHD4 | c.2234C>T p.T745I (on ENST00000357008 / NM_001363606.2; = p.T758I on NM_001273.5) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58909389; called by muse, mutect2, varscan2
- CLCN3 | c.1705A>T p.I569F | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61628341; called by muse, mutect2
- COX11 | c.666A>C p.E222D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV54803744; called by muse, mutect2, varscan2
- DSC3 | c.2387G>A p.G796E | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV64575077; called by muse, mutect2, varscan2
- FCGRT | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV54543655; called by muse, mutect2
- MTERF4 | c.145G>T p.G49* | Nonsense Mutation (SNP) | VAF 8/103 reads (8%) | catalogued as COSV54090874; called by muse, mutect2
- NLRP13 | c.971A>C p.E324A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV61623819; called by muse, mutect2, varscan2
- PCDHGA9 | c.2030G>T p.S677I | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); catalogued as COSV54018238; called by muse, mutect2, varscan2
- PYCARD | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV56008646; called by muse, mutect2, varscan2
- SCN2A | c.5690C>T p.T1897M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51840484; called by muse, mutect2, varscan2
- SLC22A11 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV57252946, COSV57254788; called by muse, mutect2, varscan2
- SNAPC1 | c.129-1G>T p.X43_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV53521063; called by muse, mutect2, varscan2
- SOAT2 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | catalogued as rs1479269571, COSV56860902; called by muse, mutect2
- SPDL1 | c.116A>T p.N39I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV54669481; called by muse, mutect2, varscan2
- SPTBN1 | c.6929A>G p.K2310R | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV63344111; called by muse, mutect2, varscan2
- SQLE | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774489924, COSV56280389; called by muse, mutect2, varscan2
- SYT9 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV59624074; called by muse, mutect2, varscan2
- TLN1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs543841478, COSV59211200; called by muse, mutect2, varscan2
- UPP1 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as COSV57978427; called by muse, mutect2, varscan2
- USP32 | c.1598A>C p.E533A | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as COSV56276215; called by muse, mutect2, varscan2
- VWF | c.2875G>C p.G959R | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99780395; called by muse, mutect2, varscan2
- ZFP28 | c.900C>G p.G300= | Splice Region (SNP) | VAF 9/63 reads (14%) | catalogued as COSV56737824; called by muse, mutect2, varscan2
- ZNF813 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV67176882, COSV67177871; called by muse, mutect2, varscan2
- BRPF1 | c.1795dup p.E599Gfs*63 | Frame Shift Ins (INS) | VAF 44/139 reads (32%) | called by mutect2, pindel, varscan2
- KMT2A | c.1167dup p.E390Rfs*34 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- MAN2B2 | c.758_762del p.P253Hfs*35 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.3303del p.N1102Mfs*6 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.1110C>T p.C370= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs534391651, COSV60101103; called by muse, mutect2, varscan2
- AMER2 | c.1483C>A p.R495= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV63439933; called by muse, mutect2, varscan2
- ARHGEF39 | c.759T>C p.D253= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58398149; called by muse, mutect2, varscan2
- CDCA2 | c.1155A>C p.L385= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV57948279; called by muse, mutect2, varscan2
- GUCY1A2 | c.909G>A p.K303= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV56499401; called by muse, mutect2, varscan2
- IGHV1-46 | c.255C>A p.G85= | Silent (SNP) | VAF 53/231 reads (23%) | catalogued as rs1555524721; called by muse, mutect2, varscan2
- INSL6 | c.249G>A p.P83= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as rs146054352, COSV67563407; called by muse, mutect2
- MED27 | c.372A>G p.A124= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV52605297; called by muse, mutect2, varscan2
- MOG | c.132G>C p.L44= | Silent (SNP) | VAF 69/285 reads (24%) | catalogued as COSV65321694; called by muse, mutect2, varscan2
- PCDHB6 | c.1803G>A p.S601= | Silent (SNP) | VAF 27/150 reads (18%) | catalogued as rs782073624, COSV50722800; called by muse, mutect2, varscan2
- SMCP | c.174C>T p.C58= | Silent (SNP) | VAF 20/243 reads (8%) | catalogued as COSV64217893; called by muse, mutect2
